Somatic mutation profile of tumor specimen C3N-00512-01 (aliquot CPT0078160007) from CPTAC case C3N-00512, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 42.6 years (15,559 days).
Specimen C3N-00512-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e517e080-929a-483c-ba32-9af94079c21f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00512-31 (Blood Derived Normal), aliquot CPT0078220002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3c22650-1f0d-4bde-812f-309e1ef02c3c

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP13 | c.1103C>A p.S368Y | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV63456387; called by muse, mutect2
- CDKN2A | c.256G>C p.A86P | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as CM097979; called by muse, mutect2
- FAM71E1 | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1237243194, COSV58541729; called by muse, mutect2
- MISP | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1327279113; called by muse, mutect2
- PCDHGA2 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1389707234, COSV53989059; called by muse, mutect2
- SHROOM2 | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1398194619, COSV66604211; called by muse, mutect2
- CPEB2 | c.2432C>A p.P811Q | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRDM14 | c.69G>A p.P23= | Silent (SNP) | VAF 15/176 reads (9%) | called by muse, mutect2
- RYR1 | c.14718G>A p.A4906= | Silent (SNP) | VAF 23/400 reads (6%) | catalogued as rs575960373; ClinVar: likely benign; called by muse, mutect2
- SNRPA1 | c.310-14C>G | Intron (SNP) | VAF 13/266 reads (5%) | called by muse, mutect2
